Surgical pathology report (de-identified scan), TCGA case TCGA-YG-AA3O, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Puerto Rico, specimen TCGA-YG-AA3O-06A (Metastatic).

ICD 0.3
Melanoma NOS 8720/3
Site Axillary lymph node
0773
p 5/30/14

Surgical Pathology and Cytopathology

Name	Age
Lab No.	Rec.Number
Phys	Ins. Plan
Date of Birth	Room No.
Date of Procedure	Date Received
Date Report	

Tissue Examination Report:

Specimen :

A) SPECIMEN unlabeled, consists of an elliptical fragment of skin with adipose tissue attached, the skin measuring 11 x 4.5 cm. The adipose tissue measures 10.5 x 10 cm. The skin is tannish brown and slightly wrinkled. On section a multinodular, roundish mass is identified measuring 7.5 x 7 x 6 cm. The mass presents a tannish brown color, being nodular and coarse, extending into the inked margins of the specimen. The tumor also extends very close to the skin. Margins inked.
(12 cassettes)

B) SPECIMEN labeled left axillary mass, metastatic melanoma, consists of an irregular fragment of yellowish adipose tissue measuring 10.5 x 5 cm. On section several lymph nodes are identified, some of them with metastatic disease.
(4 cassettes)

DIAGNOSIS:

A) LEFT, AXILLARY DISSECTION:

- METASTATIC MELANOMA TO MATTED LYMPH NODES.
- EXTRANODAL TUMORAL EXTENSION OBSERVED.
- THE TUMOR EXTENDS INTO THE INKED MARGIN OF THE SPECIMEN.
- NECROSIS PRESENT.

B) LEFT AXILLA:

- METASTATIC MELANOMA TO FOUR (4) OUT OF ELEVEN (11) LYMPH NODES.

Pathologic Staging: pTx pN3 pMx

Pathologist

This report is confidential and contains privileged information. Inappropriate disclosure

if by accident you receive this report please contact us immediately

Source: NCI Genomic Data Commons file f004b260-6ffe-4963-bf78-cbaa2b1d8b35 (TCGA-YG-AA3O.4C358082-E41F-491D-8F0D-39B2B698995A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).